Somatic mutation profile of tumor specimen TCGA-AB-2938-03A (aliquot TCGA-AB-2938-03A-01W-0732-08) from TCGA case TCGA-AB-2938, project TCGA-LAML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute megakaryoblastic leukaemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 76.3 years (27,881 days).
Specimen TCGA-AB-2938-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 95198ed7-9b23-4ebd-a899-99cfb1f603f3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AB-2938-11A (Solid Tissue Normal), aliquot TCGA-AB-2938-11A-01W-0732-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d6d6bf3a-a1d0-4a50-b6a3-e3b923914687

The open-access MAF lists 31 somatic variants for this specimen: 26 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 21, Silent 5, Frame Shift Del 3, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.1024del p.R342Efs*3 | Frame Shift Del (DEL) | VAF 50/296 reads (17%) | catalogued as rs1131691022, CM004908, COSV52665487; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TP53 | c.536A>G p.H179R | Missense Mutation (SNP) | VAF 193/316 reads (61%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1057519991, COSV52661025, COSV52661712, COSV52690692, COSV52937418; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CD320 | c.221G>C p.C74S | Missense Mutation (SNP) | VAF 21/35 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56848579; called by muse, mutect2, varscan2
- CSMD3 | c.10898T>A p.I3633N (on ENST00000297405 / NM_001363185.1; = p.I3464N on NM_052900.3) | Missense Mutation (SNP) | VAF 18/248 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.822); catalogued as COSV99828531; called by muse, mutect2
- CUL1 | c.723G>T p.E241D | Missense Mutation (SNP) | VAF 60/203 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.79); catalogued as COSV100296459, COSV57389848; called by muse, mutect2, varscan2
- DLC1 | c.3256C>T p.R1086C (on ENST00000276297 / NM_001348081.2; = p.R649C on NM_006094.5) | Missense Mutation (SNP) | VAF 53/162 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.466); catalogued as rs766774033, COSV52311544; called by muse, mutect2, varscan2
- DNMT3A | c.943del p.M315* | Frame Shift Del (DEL) | VAF 24/105 reads (23%) | catalogued as COSV53061069; called by mutect2, pindel, varscan2
- EDC4 | c.1093C>T p.P365S | Missense Mutation (SNP) | VAF 41/158 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.888); catalogued as COSV62766607; called by muse, mutect2, varscan2
- ELF4 | c.700C>T p.R234* | Nonsense Mutation (SNP) | VAF 11/214 reads (5%) | catalogued as COSV100257239; called by muse, mutect2
- EPG5 | c.1159G>C p.V387L | Missense Mutation (SNP) | VAF 16/173 reads (9%) | SIFT tolerated (0.35); PolyPhen benign (0.009); catalogued as COSV99956764; called by muse, mutect2
- KRTAP4-2 | c.229C>T p.R77C | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs200563477, COSV100894571; called by muse, mutect2, varscan2
- MYH1 | c.3419G>A p.R1140H | Missense Mutation (SNP) | VAF 52/190 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.665); catalogued as rs779598062, COSV56846716; called by muse, mutect2, varscan2
- NPTXR | c.934G>A p.A312T | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT tolerated (0.72); PolyPhen benign (0.095); catalogued as COSV60728708; called by muse, mutect2, varscan2
- NRXN3 | c.977A>G p.E326G (on ENST00000557594 / NM_001272020.2; = p.E958G on NM_004796.6) | Missense Mutation (SNP) | VAF 123/456 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.024); catalogued as COSV55335636; called by muse, mutect2, varscan2
- OR8B12 | c.773A>G p.Y258C | Missense Mutation (SNP) | VAF 58/214 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs1565380092, COSV60912077; called by muse, mutect2, varscan2
- PIK3CB | c.204G>A p.M68I | Missense Mutation (SNP) | VAF 54/264 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as COSV56687393; called by muse, mutect2, varscan2
- PRKCG | c.1738C>T p.R580W | Missense Mutation (SNP) | VAF 39/153 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs149266855, COSV99669369; called by muse, mutect2, varscan2
- RBPJ | c.136C>T p.Q46* | Nonsense Mutation (SNP) | VAF 10/224 reads (4%) | catalogued as COSV100623554; called by muse, mutect2
- ROBO2 | c.97G>A p.G33R | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.001); catalogued as COSV72216040; called by muse, mutect2, varscan2
- SIDT2 | c.2135A>G p.N712S | Missense Mutation (SNP) | VAF 155/538 reads (29%) | SIFT tolerated (0.38); PolyPhen benign (0.216); catalogued as rs376002565; called by muse, mutect2, varscan2
- SMC4 | c.2524C>T p.L842F | Missense Mutation (SNP) | VAF 13/410 reads (3%) | SIFT tolerated (0.16); PolyPhen benign (0.272); catalogued as COSV100643979; called by muse, mutect2
- TTBK1 | c.723G>T p.K241N | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV52493070; called by muse, mutect2, varscan2
- TUBA3C | c.679C>A p.L227I | Missense Mutation (SNP) | VAF 67/239 reads (28%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.098); catalogued as COSV67139540; called by muse, mutect2, varscan2
- UGT2B4 | c.1166C>T p.P389L | Missense Mutation (SNP) | VAF 72/511 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59318134; called by muse, mutect2, varscan2
- VARS2 | c.1207G>A p.E403K | Missense Mutation (SNP) | VAF 32/131 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.457); catalogued as COSV58913065; called by muse, mutect2, varscan2
- ZNF827 | c.1279del p.Q427Rfs*22 | Frame Shift Del (DEL) | VAF 29/131 reads (22%) | called by mutect2, pindel, varscan2
- CAMSAP1 | c.2007A>G p.P669= | Silent (SNP) | VAF 14/43 reads (33%) | catalogued as COSV56724203; called by muse, mutect2, varscan2
- CCZ1 | c.474C>T p.D158= | Silent (SNP) | VAF 21/68 reads (31%) | catalogued as rs770860377, COSV58074433; called by muse, mutect2, varscan2
- GOLM2 | c.1110G>A p.P370= | Silent (SNP) | VAF 23/77 reads (30%) | catalogued as rs370148920, COSV55465529; called by muse, mutect2, varscan2
- HDGF | c.564G>A p.E188= | Silent (SNP) | VAF 18/61 reads (30%) | catalogued as COSV61976717; called by muse, mutect2, varscan2
- SORBS2 | c.1896C>T p.S632= | Silent (SNP) | VAF 11/53 reads (21%) | catalogued as rs778682404, COSV53005040; called by muse, mutect2, varscan2
